Somatic mutation profile of tumor specimen MP2PRT-PAPDGX-TMP1-A (aliquot MP2PRT-PAPDGX-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPDGX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,094 days).
Specimen MP2PRT-PAPDGX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ac24f76-1c46-46c0-9204-1af56fae5150.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPDGX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPDGX-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46c35fbe-a5a8-4b27-ad13-12df2f13ebbc

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 17, Silent 5, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 241/571 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201121311, COSV55392980; called by muse, mutect2, varscan2
- AL121899.2 | c.1942G>A p.V648M | Missense Mutation (SNP) | VAF 74/500 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs780832990; called by muse, mutect2, varscan2
- FAM160A2 | c.2075C>T p.S692L (on ENST00000449352 / NM_001098794.2; = p.S706L on NM_032127.4) | Missense Mutation (SNP) | VAF 347/713 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs371804376; called by muse, mutect2, varscan2
- FGF10 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV52936457; called by muse, mutect2
- FLG | c.5338G>A p.G1780R | Missense Mutation (SNP) | VAF 106/599 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs749386933, COSV64246041; called by muse, mutect2, varscan2
- MAFK | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 148/870 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs765345967; called by muse, mutect2, varscan2
- MAP1B | c.5270G>C p.R1757T | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99702368; called by muse, mutect2, varscan2
- MUC16 | c.38538C>A p.S12846R | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.632); catalogued as rs1398366247; called by muse, mutect2, varscan2
- OR10G2 | c.195C>A p.Y65* | Nonsense Mutation (SNP) | VAF 218/512 reads (43%) | catalogued as COSV101606927; called by muse, varscan2
- PRKG1 | c.451G>C p.V151L | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.055); catalogued as COSV64815562; called by muse, mutect2, varscan2
- SHISAL1 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 244/541 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs201812933; called by muse, mutect2, varscan2
- STX5 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 100/245 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.114); catalogued as rs199744345; called by muse, mutect2, varscan2
- UHRF1 | c.1394dup p.Y466Lfs*2 (on ENST00000612630 / NM_001290050.1; = p.Y479Lfs*2 on NM_013282.4) | Frame Shift Ins (INS) | VAF 110/249 reads (44%) | catalogued as rs1167678868; called by mutect2, pindel, varscan2
- CDK3 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 23/458 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- FSIP2 | c.10684G>A p.E3562K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-53 | c.349_350insGGGGGGAG | In Frame Ins (INS) | VAF 30/54 reads (56%) | called by muse*, pindel
- LRP1B | c.8212A>G p.I2738V | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIP4P1 | c.661del p.L221Ffs*47 | Frame Shift Del (DEL) | VAF 212/548 reads (39%) | called by mutect2, pindel, varscan2
- PTCHD3 | c.2641C>G p.Q881E | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLNRD1 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 28/844 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.417); called by muse, mutect2
- TRIM13 | c.1101dup p.S368Ifs*17 | Frame Shift Ins (INS) | VAF 47/168 reads (28%) | called by mutect2, pindel, varscan2
- ZNF711 | c.1163G>T p.C388F | Missense Mutation (SNP) | VAF 61/66 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AJM1 | c.2403C>T p.A801= | Silent (SNP) | VAF 202/1163 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP12 | c.1053G>A p.G351= | Silent (SNP) | VAF 69/171 reads (40%) | catalogued as rs1483978276; called by muse, mutect2, varscan2
- CHAT | c.192G>A p.A64= | Silent (SNP) | VAF 332/746 reads (45%) | called by muse, mutect2, varscan2
- DDX43 | c.1581G>A p.E527= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV64813563; called by muse, mutect2, varscan2
- LRRK2 | c.2718G>A p.K906= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV54143953; called by muse, mutect2, varscan2
